Somatic mutation profile of tumor specimen TCGA-HC-A6AQ-01A (aliquot TCGA-HC-A6AQ-01A-11D-A30E-08) from TCGA case TCGA-HC-A6AQ, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 60.8 years (22,208 days).
Specimen TCGA-HC-A6AQ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 486ed15b-a06a-4f9d-bce0-82b395147eef.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HC-A6AQ-10A (Blood Derived Normal), aliquot TCGA-HC-A6AQ-10A-01D-A30H-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9e71d64e-cc0e-46d6-b710-694ee17d6ab7

The open-access MAF lists 26 somatic variants for this specimen: 19 protein-altering or splice-affecting, 7 silent.
By variant classification: Missense Mutation 18, Silent 7, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CGB7 | c.76C>T p.R26W | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs749912361, COSV62282607; called by muse, mutect2, varscan2
- COLEC10 | c.329G>T p.G110V | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60523074; called by muse, mutect2, varscan2
- FHOD1 | c.2794T>C p.F932L | Missense Mutation (SNP) | VAF 20/139 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.418); catalogued as COSV50771776; called by muse, mutect2, varscan2
- GPR158 | c.2485G>A p.E829K | Missense Mutation (SNP) | VAF 28/192 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.116); catalogued as COSV66279657; called by muse, mutect2, varscan2
- KCNB2 | c.1734A>C p.E578D | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT tolerated, low confidence (0.48); PolyPhen possibly damaging (0.634); catalogued as COSV73053227; called by muse, mutect2
- KIDINS220 | c.2533A>T p.N845Y | Missense Mutation (SNP) | VAF 9/100 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56757340; called by muse, mutect2
- LAMA3 | c.8939C>T p.T2980I (on ENST00000313654 / NM_198129.4; = p.T1371I on NM_000227.6) | Missense Mutation (SNP) | VAF 17/136 reads (13%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as COSV52544430; called by muse, mutect2, varscan2
- MCHR1 | c.116G>A p.G39E | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.998); catalogued as COSV50763147; called by muse, mutect2
- ME1 | c.721C>T p.L241F | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1387454836, COSV63842939; called by muse, mutect2
- MUC16 | c.3908C>A p.S1303Y | Missense Mutation (SNP) | VAF 5/90 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.18); catalogued as COSV67498168; called by muse, mutect2
- POLQ | c.2786G>C p.S929T | Missense Mutation (SNP) | VAF 3/32 reads (9%) | SIFT tolerated (0.35); PolyPhen benign (0.05); catalogued as COSV51762628; called by muse, mutect2
- RAB3C | c.196G>A p.D66N | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV51431645; called by muse, mutect2, varscan2
- RBM41 | c.482G>T p.G161V | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52565537; called by muse, mutect2, varscan2
- TMEM59L | c.779C>T p.S260F | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV53241728; called by muse, mutect2, varscan2
- TRANK1 | c.6539C>T p.S2180L | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0.195); catalogued as rs1424242876, COSV57165951; called by muse, mutect2, varscan2
- TRPC7 | c.2176A>C p.K726Q | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.146); catalogued as COSV61464799; called by muse, mutect2
- XPA | c.50C>A p.P17H | Missense Mutation (SNP) | VAF 3/32 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.343); catalogued as COSV64305836; called by muse, mutect2
- ZNF106 | c.1511C>T p.S504F | Missense Mutation (SNP) | VAF 19/108 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as COSV55522500; called by muse, mutect2, varscan2
- FITM2 | c.397del p.E133Nfs*27 | Frame Shift Del (DEL) | VAF 8/66 reads (12%) | called by mutect2, pindel, varscan2
- KBTBD12 | c.1146T>C p.S382= | Silent (SNP) | VAF 8/96 reads (8%) | catalogued as COSV59682194; called by muse, mutect2
- MAP2K4 | c.945T>C p.D315= | Silent (SNP) | VAF 3/36 reads (8%) | catalogued as COSV62261236; called by muse, mutect2
- NRDE2 | c.2304G>A p.K768= | Silent (SNP) | VAF 8/168 reads (5%) | catalogued as rs1342508159, COSV62964958; called by muse, mutect2
- OLFM3 | c.1263C>T p.S421= (on ENST00000338858 / NM_001288821.1; = p.S401= on NM_058170.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 8/134 reads (6%) | catalogued as COSV100129011, COSV58805039; called by muse, mutect2
- PANX2 | c.474G>T p.L158= | Silent (SNP) | VAF 4/22 reads (18%) | catalogued as rs764530663, COSV50318401; called by muse, mutect2, varscan2
- PCDH8 | c.2850G>A p.A950= | Silent (SNP) | VAF 7/46 reads (15%) | catalogued as rs764149792, COSV58815267; called by muse, mutect2, varscan2
- UTP20 | c.6853T>C p.L2285= | Silent (SNP) | VAF 4/44 reads (9%) | catalogued as COSV55386321; called by muse, mutect2
